FM case AD2035 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/c1e0f40c-5c10-4abd-8f64-7bf19c82ec1b

Male, 70.6 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the parotid gland. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
